Somatic mutation profile of tumor specimen TCGA-D5-6931-01A (aliquot TCGA-D5-6931-01A-11D-1924-10) from TCGA case TCGA-D5-6931, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 77.5 years (28,292 days).
Specimen TCGA-D5-6931-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 689c7d07-77b7-4ecb-9eb0-47477895ae2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6931-10A (Blood Derived Normal), aliquot TCGA-D5-6931-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfabe72a-4a60-48d2-93f1-657389747dc6

The open-access MAF lists 329 somatic variants for this specimen: 250 protein-altering or splice-affecting, 74 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 227, Silent 74, Nonsense Mutation 12, Frame Shift Ins 4, RNA 3, Splice Site 3, Intron 2, Frame Shift Del 2, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 30/44 reads (68%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 53/143 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1057519732, COSV61068297; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 46/252 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SCN1A | c.5734C>T p.R1912* (on ENST00000303395 / NM_001202435.3; = p.R1901* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 23/101 reads (23%) | catalogued as rs77216276, CD114895, CM044053, COSV57661348; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893810, CM050761, CM140638, COSV55443375, COSV55461069, COSV99848566; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 30/54 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs397514495, CM056067, CM920671, CM942120, COSV52675795, COSV52676870, COSV52730435, COSV53567603; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.68923C>T p.R22975* (on ENST00000591111; = p.R15551* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 25/105 reads (24%) | catalogued as rs794729284, COSV59904714; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.3197A>C p.K1066T | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.262); catalogued as COSV53963609, COSV53966064; called by muse, mutect2, varscan2
- ACAN | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369864209; called by muse, mutect2, varscan2
- ADAMTS1 | c.944A>C p.E315A | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.223); catalogued as COSV53168836; called by muse, mutect2, varscan2
- ADAMTS9 | c.1945T>G p.F649V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55775681, COSV55781947; called by muse, mutect2, varscan2
- ADGRG3 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs376154437, COSV59650277, COSV59651601; called by muse, mutect2, varscan2
- AKAP3 | c.2360T>C p.V787A | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57414298; called by muse, mutect2, varscan2
- AL441992.2 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs572629163, COSV56912492; called by muse, mutect2, varscan2
- ALAS2 | c.596A>C p.Y199S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100238602; called by muse, varscan2
- ALPP | c.1273G>T p.D425Y | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV67395708; called by muse, varscan2
- ANOS1 | c.1775T>G p.V592G | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52916318; called by muse, mutect2, varscan2
- AP3D1 | c.2959G>A p.G987S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as rs778410062, COSV61424798; called by muse, mutect2, varscan2
- APOB | c.6542T>G p.F2181C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51929739, COSV99267719; called by muse, mutect2, varscan2
- APOB | c.4465C>A p.Q1489K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV99267723; called by muse, mutect2, varscan2
- AREL1 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs926854848, COSV62665527; called by muse, mutect2, varscan2
- ARMC3 | c.1438G>T p.G480C | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53057558; called by muse, mutect2, varscan2
- ARMCX1 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 49/64 reads (77%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.077); catalogued as COSV65704912; called by muse, mutect2, varscan2
- ATAD2 | c.849A>T p.E283D | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs73341764; called by muse, varscan2
- ATP8A2 | c.2923C>A p.L975I | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs748713859, COSV54938696, COSV54944361; called by muse, mutect2, varscan2
- ATP8B2 | c.2570C>T p.T857M (on ENST00000672630; = p.T824M on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as rs777449123, COSV59244861; called by muse, mutect2, varscan2
- BEND2 | c.1936C>T p.R646* | Nonsense Mutation (SNP) | VAF 64/140 reads (46%) | catalogued as rs933709144, COSV101192064, COSV66215159; called by muse, mutect2, varscan2
- BNC1 | c.2508A>C p.Q836H | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV61756603; called by muse, mutect2, varscan2
- BTK | c.569C>A p.P190Q | Missense Mutation (SNP) | VAF 76/104 reads (73%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.77); catalogued as CD982517, COSV58117614; called by muse, mutect2, varscan2
- BTNL8 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs751803412, COSV51457013; called by muse, mutect2, varscan2
- CACNA1I | c.2707C>T p.L903F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.617); catalogued as COSV60801864; called by muse, mutect2, varscan2
- CAPN6 | c.1844A>G p.K615R | Missense Mutation (SNP) | VAF 61/83 reads (73%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV60693990; called by muse, mutect2, varscan2
- CASZ1 | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.254); catalogued as rs768854834, COSV100682119; called by muse, mutect2, varscan2
- CCDC39 | c.1036T>G p.L346V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.671); catalogued as COSV56479232; called by muse, mutect2, varscan2
- CDH13 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.173); catalogued as rs1567797885, COSV51794489, COSV99229022; called by muse, mutect2, varscan2
- CDH2 | c.1727T>G p.L576R | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV52272701; called by muse, mutect2, varscan2
- CDH2 | c.329A>C p.E110A | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV52272711; called by muse, mutect2, varscan2
- CDK1 | c.632A>G p.D211G | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV57349022; called by muse, mutect2, varscan2
- CEACAM18 | c.778T>G p.F260V | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV67282217; called by muse, mutect2, varscan2
- CEBPZ | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 23/75 reads (31%) | catalogued as COSV50016953; called by muse, mutect2, varscan2
- CEP95 | c.1625C>T p.T542M | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs199726407, COSV73608675; called by muse, mutect2, varscan2
- CHRM2 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as COSV57766199; called by muse, mutect2, varscan2
- CHRM3 | c.629T>G p.F210C | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55081319; called by muse, mutect2, varscan2
- CILP | c.2933G>A p.R978Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as rs373252930; called by muse, mutect2, varscan2
- CLEC14A | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV60561794; called by muse, mutect2, varscan2
- CLSPN | c.1003A>T p.K335* | Nonsense Mutation (SNP) | VAF 41/193 reads (21%) | catalogued as COSV52047296; called by muse, mutect2, varscan2
- CNTN6 | c.2606T>C p.L869P | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63172782; called by muse, mutect2, varscan2
- CRMP1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs868118770, COSV61478429; called by muse, mutect2, varscan2
- CUBN | c.4680A>C p.Q1560H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV100913457, COSV64713988; called by muse, mutect2, varscan2
- CXorf58 | c.880A>G p.K294E | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as COSV64857862; called by muse, mutect2, varscan2
- CYP4F8 | c.1519C>G p.R507G | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368455652, COSV100358230; called by muse, mutect2, varscan2
- CYP7B1 | c.254T>C p.L85P | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100043309, COSV59583035; called by muse, mutect2, varscan2
- DAGLA | c.1180G>A p.V394M | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57194344; called by muse, mutect2, varscan2
- DDX18 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 66/279 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV54305473, COSV99604397; called by muse, mutect2, varscan2
- DENND2A | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1390710116, COSV52048139, COSV52061975; called by muse, mutect2, varscan2
- DENND5A | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs769758504, COSV60232740; called by muse, mutect2, varscan2
- DHX32 | c.1517T>A p.V506E | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV52938432; called by muse, mutect2, varscan2
- DNAH11 | c.5543T>G p.I1848S | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100180619; called by muse, mutect2, varscan2
- DNAH5 | c.13276G>A p.E4426K | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs777295839, COSV54202122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC10 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as rs371494397; called by muse, mutect2, varscan2
- DSCAML1 | c.388G>A p.V130M (on ENST00000321322; = p.V70M on NM_020693.4) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1393957887, COSV58382031; called by muse, mutect2, varscan2
- DSEL | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778536579, COSV59489612; called by muse, mutect2, varscan2
- DYNC1LI1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.939); catalogued as COSV56126878; called by muse, mutect2, varscan2
- EBF1 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV58168718; called by muse, mutect2
- EP300 | c.1759C>T p.L587F | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54327216; called by muse, mutect2, varscan2
- ERBB3 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.572); catalogued as rs1429784531, COSV57247034, COSV99915945; called by muse, mutect2, varscan2
- ERICH3 | c.2197G>T p.A733S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.349); catalogued as COSV100445563; called by muse, mutect2, varscan2
- FAM189A2 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.635); catalogued as rs184081860; called by muse, mutect2, varscan2
- FAT4 | c.6710C>T p.T2237I | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV100630009; called by muse, mutect2, varscan2
- FUT9 | c.693G>C p.L231F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV56142742; called by muse, mutect2, varscan2
- GABRA6 | c.518A>C p.K173T | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs1270279109, COSV50877438, COSV99194040; called by muse, mutect2, varscan2
- GAD2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); catalogued as COSV52151057; called by muse, mutect2, varscan2
- GAP43 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59342699; called by muse, mutect2, varscan2
- GDF15 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as rs114827523, COSV53250490; called by muse, mutect2, varscan2
- GDF9 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs751002918, COSV51525840; called by muse, mutect2, varscan2
- GFRA1 | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs753551884, COSV62605267, COSV62609868; called by muse, mutect2, varscan2
- GHR | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs865987331, COSV50106764; called by muse, mutect2, varscan2
- GNAT2 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV63554650; called by muse, mutect2, varscan2
- GPAM | c.414-1G>A p.X138_splice | Splice Site (SNP) | VAF 6/114 reads (5%) | catalogued as rs1401590489; called by muse, mutect2
- GRIA1 | c.2012A>C p.E671A | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV99602147; called by muse, mutect2, varscan2
- GRIK4 | c.701T>G p.L234R | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV70801038, COSV70803021; called by muse, mutect2, varscan2
- GUCY2F | c.2057T>C p.V686A | Missense Mutation (SNP) | VAF 123/159 reads (77%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV54298929; called by muse, mutect2, varscan2
- HARS1 | c.440T>G p.I147S | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV56905646; called by muse, mutect2, varscan2
- HLA-A | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs45542135, COSV65137690, COSV65137726; called by muse, mutect2, varscan2
- HLA-B | c.917del p.V306Afs*13 | Frame Shift Del (DEL) | VAF 68/147 reads (46%) | catalogued as COSV69520520; called by mutect2, varscan2
- HMCN1 | c.3080A>C p.K1027T | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.505); catalogued as COSV54889062, COSV99623133, COSV99637782; called by muse, mutect2, varscan2
- HS1BP3 | c.617T>A p.I206N | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV58312044; called by muse, mutect2, varscan2
- HTR2A | c.262A>C p.T88P | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101096831; called by muse, mutect2, varscan2
- IFI16 | c.2006C>T p.A669V (on ENST00000295809 / NM_001364867.2; = p.A613V on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55531380; called by muse, mutect2, varscan2
- IGF2BP3 | c.1357A>C p.M453L | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.146); catalogued as rs866229652, COSV51680362; called by muse, mutect2, varscan2
- IL20RB | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs763416984, COSV59046840; called by muse, mutect2, varscan2
- ILVBL | c.1564G>A p.G522R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369517673; called by muse, mutect2, varscan2
- INTS5 | c.1511G>A p.G504D | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.708); catalogued as COSV100399793; called by muse, mutect2, varscan2
- IPO4 | c.3008G>A p.R1003H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs369101802; called by muse, mutect2, varscan2
- ITGA8 | c.2203G>A p.G735R | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV65225164; called by muse, mutect2, varscan2
- ITIH2 | c.1019T>G p.L340R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64432081; called by muse, mutect2, varscan2
- ITSN2 | c.1030C>G p.L344V | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.159); catalogued as COSV100743996; called by muse, mutect2
- KDR | c.3461C>A p.S1154* | Nonsense Mutation (SNP) | VAF 25/94 reads (27%) | catalogued as COSV55758670, COSV55777803; called by muse, mutect2, varscan2
- KRT34 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs767269385, COSV67449159; called by muse, mutect2
- KRTAP6-3 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 28/137 reads (20%) | PolyPhen probably damaging (0.945); catalogued as COSV66962684; called by muse, mutect2, varscan2
- LAMC3 | c.3815C>T p.A1272V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs146180154, COSV62653367; called by muse, mutect2, varscan2
- LHFPL3 | c.110A>C p.N37T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.908); catalogued as COSV101308817, COSV67808649; called by muse, mutect2, varscan2
- LIN7A | c.132A>C p.E44D | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV54017493, COSV99691577, COSV99691982; called by muse, mutect2, varscan2
- LONRF2 | c.1310G>A p.S437N | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV66539479; called by muse, mutect2, varscan2
- LRGUK | c.915A>T p.E305D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV53634436; called by muse, mutect2, varscan2
- LRRCC1 | c.2869G>T p.D957Y | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64482676; called by muse, mutect2, varscan2
- LRRTM1 | c.1203G>T p.Q401H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV54438553; called by muse, mutect2, varscan2
- LRTM2 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV54564063; called by muse, mutect2, varscan2
- LVRN | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs142239251, COSV63496163; called by muse, mutect2, varscan2
- LYSMD2 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 26/113 reads (23%) | catalogued as COSV51056665; called by muse, mutect2, varscan2
- MATK | c.1151G>A p.S384N (on ENST00000310132 / NM_139355.3; = p.S385N on NM_002378.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.169); catalogued as COSV59553275; called by muse, mutect2
- MEPCE | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV52768749; called by muse, mutect2, varscan2
- MEPCE | c.1926G>T p.L642F | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as COSV52768758; called by muse, mutect2, varscan2
- MRPL16 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV100276536; called by muse, mutect2, varscan2
- MUC16 | c.39013A>G p.T13005A | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs756739393, COSV67447531; called by muse, mutect2, varscan2
- MUC16 | c.25787T>C p.L8596P | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV67447536; called by muse, mutect2, varscan2
- MYH4 | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV99702128; called by muse, mutect2, varscan2
- NAPEPLD | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV100085612; called by muse, mutect2, varscan2
- NCAM1 | c.1593A>C p.E531D (on ENST00000316851 / NM_181351.5; = p.E521D on NM_000615.7) | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57511155; called by muse, mutect2, varscan2
- NEK1 | c.390A>T p.K130N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71454701; called by muse, mutect2, varscan2
- NEK8 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV52043149; called by muse, mutect2, varscan2
- NLGN4X | c.104A>C p.K35T | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV52005941; called by muse, mutect2, varscan2
- NLGN4Y | c.220T>G p.L74V | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52969210; called by muse, mutect2, varscan2
- NLRP4 | c.24T>G p.D8E | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs770275628, COSV56708512; called by muse, mutect2, varscan2
- NLRP4 | c.1832A>C p.K611T | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV56708522, COSV56717605; called by muse, mutect2, varscan2
- NLRP5 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537471101, COSV66762321; called by muse, mutect2, varscan2
- NOTCH4 | c.3797G>A p.G1266E | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV66678952; called by muse, mutect2, varscan2
- NRK | c.1630C>A p.Q544K | Missense Mutation (SNP) | VAF 58/78 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs752168538, COSV54590641; called by muse, mutect2, varscan2
- NTRK3 | c.1732A>G p.T578A | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV100713792; called by muse, mutect2
- NYAP2 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV55999264; called by muse, mutect2, varscan2
- OBSCN | c.21308T>C p.I7103T | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100805412; called by muse, mutect2, varscan2
- OLFML2A | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56582028; called by muse, mutect2, varscan2
- OR10G8 | c.307T>A p.F103I | Missense Mutation (SNP) | VAF 67/279 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV70908200; called by muse, mutect2, varscan2
- OR10J3 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV59953599, COSV59953705; called by muse, mutect2, varscan2
- OR11H4 | c.916G>C p.D306H | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV59559808; called by muse, mutect2, varscan2
- OR1A2 | c.746dup p.L249Ffs*41 | Frame Shift Ins (INS) | VAF 28/134 reads (21%) | catalogued as rs781401043; called by mutect2, varscan2
- OR2M2 | c.625T>G p.F209V | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.562); catalogued as COSV62897665; called by muse, mutect2, varscan2
- OR4P4 | c.572A>C p.H191P | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.433); catalogued as COSV58920790; called by muse, mutect2, varscan2
- OR52A5 | c.427T>G p.L143V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV56613991, COSV56614404; called by mutect2, varscan2
- OR56A3 | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100290365; called by muse, mutect2, varscan2
- OR6Q1 | c.88T>G p.F30V | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV56932257; called by muse, mutect2, varscan2
- PATZ1 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV53228812; called by muse, mutect2
- PCDH11Y | c.854A>G p.E285G (on ENST00000400457 / NM_032973.2; = p.E274G on NM_032971.3) | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV53075131; called by muse, mutect2, varscan2
- PCDH18 | c.1255A>C p.T419P | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61269844; called by muse, mutect2, varscan2
- PCDHA2 | c.1247A>G p.E416G | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65364946; called by muse, mutect2, varscan2
- PCDHB11 | c.628T>G p.F210V | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.156); catalogued as COSV53375730; called by muse, mutect2, varscan2
- PCDHB14 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.013); catalogued as rs370360628; called by muse, mutect2, varscan2
- PDGFD | c.811A>C p.S271R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755849936, COSV100160702, COSV56394207; called by mutect2, varscan2
- PHOX2B | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56928567; called by muse, mutect2, varscan2
- PLCZ1 | c.40T>A p.F14I | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56849392, COSV56852893; called by muse, mutect2, varscan2
- PLEK | c.794A>C p.K265T | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV52250717, COSV99311275; called by muse, mutect2, varscan2
- PMS2 | c.1034T>C p.L345P | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99764535; called by muse, mutect2, varscan2
- PODNL1 | c.1436G>A p.R479K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.028); catalogued as COSV99583065; called by muse, mutect2
- PPFIA2 | c.2236A>C p.S746R | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV61019199, COSV61021719; called by muse, mutect2, varscan2
- PPP1R7 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs777048169, COSV52143710; called by muse, mutect2, varscan2
- PRB2 | c.1244C>G p.P415R | Missense Mutation (SNP) | VAF 34/245 reads (14%) | PolyPhen benign (0.331); catalogued as COSV101231487; called by muse, varscan2
- PROX2 | c.908T>C p.L303S | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as COSV101507824; called by muse, mutect2
- PRPF31 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.137); catalogued as rs762463081, COSV58084600; called by muse, mutect2, varscan2
- PRSS33 | c.557C>A p.P186Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV53450385, COSV53450466; called by muse, mutect2, varscan2
- PTGFRN | c.2067A>G p.I689M | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as COSV67797835; called by muse, mutect2, varscan2
- PTPRS | c.4126G>A p.A1376T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs200850387, COSV53611156; called by muse, mutect2, varscan2
- PXDNL | c.2030A>C p.K677T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.191); catalogued as COSV62479528; called by muse, mutect2, varscan2
- RBL1 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.464); catalogued as rs368117514; called by muse, mutect2, varscan2
- RFNG | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as rs757464403, COSV100135780, COSV57647773; called by muse, mutect2, varscan2
- RIC3 | c.1087C>T p.R363C (on ENST00000309737 / NM_001206671.4; = p.R362C on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs931814965, COSV58300603; called by muse, mutect2, varscan2
- RNF17 | c.1830A>C p.K610N | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as rs1400387373, COSV99694325; called by muse, mutect2, varscan2
- RPH3A | c.769G>A p.A257T (on ENST00000389385 / NM_001143854.2; = p.A253T on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1294164894, COSV101231785, COSV66990050; called by muse, mutect2, varscan2
- RPTOR | c.3449G>A p.W1150* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100155789, COSV100157133; called by muse, mutect2, varscan2
- RTTN | c.4653G>A p.T1551= | Splice Region (SNP) | VAF 17/59 reads (29%) | catalogued as rs143616624, COSV55341788; called by muse, mutect2, varscan2
- RUFY1 | c.2030G>T p.S677I | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV60158585, COSV60163992; called by muse, mutect2
- RUNX1T1 | c.1372C>T p.R458C (on ENST00000265814 / NM_001198628.1; = p.R431C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1381105316, COSV56138759; called by muse, mutect2, varscan2
- SAMD15 | c.1211T>C p.L404P | Missense Mutation (SNP) | VAF 78/303 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.187); catalogued as COSV99375218; called by muse, mutect2, varscan2
- SAPCD2 | c.587G>C p.R196T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV101294057, COSV68836861; called by muse, mutect2, varscan2
- SATB1 | c.1556T>G p.V519G | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58667726; called by muse, mutect2, varscan2
- SCARA3 | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201948380, COSV57269420; called by muse, mutect2, varscan2
- SCN3A | c.1955G>A p.G652D | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51802399; called by muse, mutect2, varscan2
- SCN3B | c.551T>A p.V184D | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100173848; called by muse, mutect2, varscan2
- SCUBE2 | c.1921G>A p.V641M | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs924117109, COSV58540804; called by muse, mutect2, varscan2
- SETBP1 | c.233A>G p.E78G | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV56313841; called by muse, mutect2, varscan2
- SHROOM2 | c.4847A>C p.K1616T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66604878; called by muse, mutect2, varscan2
- SLC16A4 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs754334971, COSV63916005; called by muse, mutect2, varscan2
- SLC26A7 | c.236G>A p.G79D | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368061045, COSV99404244; called by muse, mutect2, varscan2
- SLC44A5 | c.1750T>G p.F584V | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63757821, COSV63770496; called by muse, mutect2, varscan2
- SMC1B | c.2419A>G p.R807G | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV62528384; called by muse, mutect2, varscan2
- SOX9 | c.524A>C p.Q175P | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV55422525; called by muse, mutect2, varscan2
- SP7 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV58190466; called by muse, mutect2, varscan2
- SPART | c.1576A>T p.K526* | Nonsense Mutation (SNP) | VAF 54/290 reads (19%) | catalogued as COSV62083799, COSV62084744; called by muse, mutect2, varscan2
- SPATA5 | c.455A>T p.D152V | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as rs749514933, COSV56772324; called by muse, mutect2, varscan2
- SPHKAP | c.3314C>T p.T1105M | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs748558267, COSV60869706; called by muse, mutect2, varscan2
- SPTA1 | c.3327A>C p.E1109D | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63749424; called by muse, mutect2, varscan2
- SPTA1 | c.294A>C p.E98D | Missense Mutation (SNP) | VAF 66/294 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV63749427; called by muse, mutect2, varscan2
- SPZ1 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 71/260 reads (27%) | catalogued as COSV57062365; called by muse, mutect2, varscan2
- SYNE1 | c.16547A>T p.E5516V (on ENST00000367255 / NM_182961.4; = p.E5445V on NM_033071.3) | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99553104, COSV99576946; called by muse, mutect2, varscan2
- TBL2 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs372704268; called by muse, mutect2, varscan2
- TBP | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV57830832; called by muse, mutect2, varscan2
- TEC | c.284G>T p.S95I | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV67403587; called by muse, mutect2, varscan2
- TGIF2LX | c.505A>G p.R169G | Missense Mutation (SNP) | VAF 110/144 reads (76%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52213407; called by muse, mutect2, varscan2
- THSD7B | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.278); catalogued as COSV55683996; called by muse, mutect2, varscan2
- TLE4 | c.1013A>C p.N338T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99511166, COSV99513080; called by muse, mutect2, varscan2
- TLR6 | c.1032A>G p.I344M | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as COSV67935007; called by muse, mutect2, varscan2
- TM6SF1 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV51943806; called by muse, mutect2, varscan2
- TMEM145 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 67/359 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs757125287, COSV56623887; called by muse, mutect2, varscan2
- TMPRSS15 | c.328A>G p.R110G | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as rs1326456661, COSV99519199; called by muse, mutect2, varscan2
- TNN | c.1037T>C p.L346P | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.52); catalogued as COSV53422119, COSV53426205; called by muse, mutect2, varscan2
- TNRC6C | c.5047G>T p.D1683Y | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100050616; called by muse, mutect2
- TRIM51 | c.1279C>A p.Q427K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as COSV99793134; called by muse, mutect2
- TRPV6 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.263); catalogued as rs745408146, COSV63890716; called by muse, mutect2, varscan2
- TSPAN2 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.371); catalogued as rs777331815, COSV65689416; called by muse, mutect2, varscan2
- TTN | c.23313A>C p.E7771D (on ENST00000591111; = p.E6844D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | PolyPhen benign (0.009); catalogued as COSV60315445; called by muse, mutect2, varscan2
- TTN | c.20365C>A p.L6789M (on ENST00000591111; = p.L5862M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/109 reads (25%) | PolyPhen possibly damaging (0.883); catalogued as COSV59904736; called by muse, mutect2, varscan2
- TVP23A | c.100G>C p.A34P | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100243324; called by muse, mutect2
- TXN | c.129+1G>A p.X43_splice | Splice Site (SNP) | VAF 25/122 reads (20%) | catalogued as COSV65730884; called by muse, mutect2, varscan2
- UNC79 | c.2939A>T p.K980M (on ENST00000393151 / NM_001346218.2; = p.K803M on NM_020818.5) | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56375611; called by muse, mutect2, varscan2
- USP17L2 | c.1174A>G p.R392G | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100414720; called by muse, mutect2, varscan2
- USP29 | c.542A>G p.E181G | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV54140266; called by muse, mutect2, varscan2
- USP29 | c.1606A>G p.S536G | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.498); catalogued as COSV54143322, COSV54145910; called by muse, mutect2, varscan2
- VCAN | c.8404T>A p.S2802T | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as COSV54097794; called by muse, mutect2, varscan2
- VPS13B | c.5594A>C p.K1865T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV62134246; called by muse, mutect2, varscan2
- WNK2 | c.5425G>A p.D1809N (on ENST00000297954 / NM_001282394.1; = p.D1772N on NM_006648.3) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as rs762615300, COSV52932595; called by muse, mutect2
- ZBTB20 | c.1422G>T p.Q474H (on ENST00000474710 / NM_001164342.2; = p.Q401H on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100615095; called by muse, mutect2, varscan2
- ZBTB21 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1252017088, COSV60403893; called by muse, mutect2, varscan2
- ZFHX3 | c.856T>A p.L286M | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51709967; called by muse, mutect2, varscan2
- ZMAT1 | c.1756G>T p.V586F | Missense Mutation (SNP) | VAF 376/511 reads (74%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as COSV65657768, COSV65657811; called by muse, mutect2, varscan2
- ZNF146 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61931220; called by muse, mutect2, varscan2
- ZNF175 | c.1025A>C p.K342T | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99219735; called by muse, mutect2, varscan2
- ZNF211 | c.203T>C p.L68P (on ENST00000347302 / NM_198855.4; = p.L81P on NM_006385.5) | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53740718; called by muse, mutect2, varscan2
- ZNF211 | c.449T>G p.L150R (on ENST00000347302 / NM_198855.4; = p.L163R on NM_006385.5) | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV99560472; called by muse, mutect2, varscan2
- ZNF28 | c.2038C>T p.Q680* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as COSV60421878; called by muse, mutect2, varscan2
- ZNF302 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.112); catalogued as COSV101416520; called by muse, varscan2
- ZNF334 | c.935A>G p.Q312R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.249); catalogued as COSV100749196; called by muse, mutect2, varscan2
- ZNF418 | c.326T>C p.L109P | Missense Mutation (SNP) | VAF 72/522 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.986); catalogued as COSV68675601; called by muse, mutect2, varscan2
- ZNF470 | c.1247A>G p.K416R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.063); catalogued as COSV100401384, COSV100401453; called by muse, mutect2, varscan2
- ZNF493 | c.1375A>C p.T459P | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as COSV62749257; called by muse, mutect2, varscan2
- ZNF493 | c.1475A>G p.K492R | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.632); catalogued as COSV62749261; called by muse, mutect2, varscan2
- ZNF536 | c.3695A>C p.Q1232P | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV62819180, COSV62836723; called by muse, mutect2
- ZNF549 | c.625T>C p.Y209H (on ENST00000376233 / NM_001199295.2; = p.Y196H on NM_153263.2) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV53723677; called by muse, mutect2
- ZNF558 | c.909G>C p.K303N | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.943); catalogued as COSV56862448, COSV56864627; called by muse, mutect2, varscan2
- ZNF577 | c.929A>C p.K310T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV56814302; called by muse, mutect2, varscan2
- ZNF599 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs202116567; called by muse, mutect2, varscan2
- ZNF746 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as rs185564177, COSV61406452; called by muse, mutect2, varscan2
- ZNF790 | c.924A>C p.K308N | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as rs747209470, COSV63211999, COSV63212386; called by muse, mutect2, varscan2
- ZNF99 | c.100T>G p.L34V | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); catalogued as COSV68054885; called by muse, mutect2, varscan2
- CEP250 | c.626_653del p.H209Pfs*6 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel
- PCDHB9 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- PXDN | c.4012_4013dup p.E1339Lfs*66 | Frame Shift Ins (INS) | VAF 15/77 reads (19%) | called by mutect2, pindel, varscan2
- SOX9 | c.1198dup p.E400Gfs*178 | Frame Shift Ins (INS) | VAF 16/78 reads (21%) | called by mutect2, pindel
- TTN | c.12460dup p.M4154Nfs*4 (on ENST00000591111; = p.M4108Nfs*4 on NM_003319.4) | Frame Shift Ins (INS) | VAF 26/142 reads (18%) | called by mutect2, pindel, varscan2
- ZNF606 | c.31+1dup p.X11_splice | Splice Site (INS) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- ACP3 | c.912C>T p.N304= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as rs376964687; called by muse, mutect2, varscan2
- ACRBP | c.1626C>T p.F542= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs149312090, COSV57523177; called by muse, mutect2, varscan2
- ACTR10 | c.801G>A p.V267= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV54297492; called by muse, mutect2, varscan2
- ADAMTS4 | c.825C>T p.G275= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1318329637, COSV100917563; called by muse, mutect2
- ADAMTSL2 | c.804C>T p.N268= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- ALG10B | c.1039T>C p.L347= | Silent (SNP) | VAF 82/392 reads (21%) | catalogued as COSV58142436; called by muse, mutect2, varscan2
- AMIGO3 | c.546C>T p.A182= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as COSV57537637; called by muse, mutect2, varscan2
- ANKRD11 | c.708G>A p.T236= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs756858960, COSV56355650; called by muse, mutect2, varscan2
- ATP1A2 | c.36C>T p.A12= | Silent (SNP) | VAF 101/307 reads (33%) | catalogued as rs767913105, COSV63402420, COSV63403910; ClinVar: likely benign; called by muse, mutect2, varscan2
- BSN | c.10569C>T p.P3523= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs536513492, COSV56513447; called by muse, mutect2, varscan2
- C21orf58 | c.378G>A p.E126= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV52448935; called by muse, mutect2, varscan2
- CCT8L2 | c.435C>A p.A145= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV63461693; called by muse, mutect2, varscan2
- CD1D | c.265C>A p.R89= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs920079330, COSV63808455, COSV63808828; called by muse, mutect2, varscan2
- CECR2 | c.2346G>A p.S782= (on ENST00000342247 / NM_001290047.2; = p.S599= on NM_001290046.1) | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs747825289, COSV52841678, COSV99378996; called by muse, mutect2, varscan2
- CHRDL2 | c.570G>A p.S190= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs112976652; called by muse, mutect2, varscan2
- CLEC10A | c.912C>T p.C304= (on ENST00000254868 / NM_182906.4; = p.C280= on NM_006344.4) | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs147465833; called by muse, mutect2, varscan2
- COL3A1 | c.3585T>G p.P1195= | Silent (SNP) | VAF 40/154 reads (26%) | catalogued as COSV58582525; called by muse, mutect2, varscan2
- CSMD1 | c.780T>C p.D260= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV68165242; called by muse, mutect2, varscan2
- CTSL | c.384T>G p.P128= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV58245733; called by muse, mutect2, varscan2
- CYFIP2 | c.2724G>A p.Q908= (on ENST00000616178 / NM_001291722.2; = p.Q883= on NM_014376.4) | Silent (SNP) | VAF 33/147 reads (22%) | catalogued as COSV56635854; called by muse, mutect2, varscan2
- DCAF4L2 | c.237G>A p.A79= | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as COSV60476744, COSV60480732; called by muse, mutect2, varscan2
- DCDC1 | c.4098G>T p.V1366= (on ENST00000597505 / NM_001367979.1; = p.V473= on NM_020869.3) | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV57997634; called by muse, mutect2, varscan2
- DCLK1 | c.1002A>G p.S334= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as rs201566141, COSV99712848; called by muse, mutect2, varscan2
- DMTN | c.588G>A p.P196= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs767628320, COSV56111197; called by muse, mutect2, varscan2
- DRG2 | c.753C>T p.I251= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV56727744; called by muse, mutect2, varscan2
- EBF1 | c.114C>T p.D38= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV58168729; called by muse, mutect2, varscan2
- EIF2AK1 | c.366A>G p.R122= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV52236421; called by muse, mutect2, varscan2
- FAM117A | c.441C>A p.G147= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV53630828; called by muse, mutect2, varscan2
- FREM2 | c.1402T>C p.L468= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV54826828, COSV54842467; called by muse, varscan2
- GABRB3 | c.399A>C p.G133= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV54651750; called by muse, mutect2, varscan2
- GNL3L | c.1101C>T p.A367= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV60575477; called by muse, mutect2
- GPR149 | c.1704A>C p.L568= | Silent (SNP) | VAF 73/304 reads (24%) | catalogued as COSV67665943; called by muse, mutect2, varscan2
- GRIA2 | c.1851C>T p.L617= | Silent (SNP) | VAF 59/240 reads (25%) | catalogued as COSV99644720; called by muse, mutect2, varscan2
- GRM2 | c.954G>A p.E318= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV56583330; called by muse, mutect2, varscan2
- GRM3 | c.405A>G p.Q135= | Silent (SNP) | VAF 32/137 reads (23%) | catalogued as COSV64467709; called by muse, mutect2, varscan2
- HIPK1 | c.1917C>T p.T639= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV61245695; called by muse, mutect2, varscan2
- HSPD1 | c.1161G>A p.K387= | Silent (SNP) | VAF 66/248 reads (27%) | catalogued as COSV100798424; called by muse, mutect2, varscan2
- IPMK | c.387A>G p.K129= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV57266437; called by muse, mutect2, varscan2
- KCND2 | c.1839G>A p.R613= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV58570456; called by muse, mutect2, varscan2
- KIAA1210 | c.3588C>T p.F1196= | Silent (SNP) | VAF 85/116 reads (73%) | catalogued as rs202170203, COSV68175723; called by muse, mutect2, varscan2
- KRBA1 | c.2835G>A p.P945= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs755349701, COSV99753095; called by muse, varscan2
- KRTAP13-1 | c.288C>T p.Y96= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as COSV62662884; called by muse, mutect2, varscan2
- MAF | c.198G>A p.S66= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs764199478, COSV58153215, COSV58153576; called by muse, mutect2, varscan2
- MB21D2 | c.936C>T p.A312= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV66661843; called by muse, mutect2
- MED25 | c.1806G>A p.T602= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as rs760140749, COSV57203127; called by muse, mutect2, varscan2
- NKAIN1 | c.573G>A p.A191= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs1199275650, COSV55273916; called by muse, mutect2, varscan2
- NLGN3 | c.2400G>A p.P800= (on ENST00000358741 / NM_181303.2; = p.P780= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 113/151 reads (75%) | catalogued as rs759456119, COSV62441905; called by muse, mutect2
- OR10G9 | c.612A>T p.L204= | Silent (SNP) | VAF 16/308 reads (5%) | catalogued as COSV100901743; called by muse, mutect2
- OR5W2 | c.94T>C p.L32= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs1214322255, COSV60614714, COSV60614862; called by muse, mutect2, varscan2
- PAFAH1B2 | c.525C>T p.T175= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs374387074; called by muse, mutect2, varscan2
- PCDHA9 | c.210C>G p.G70= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV65323748; called by muse, mutect2, varscan2
- PDZD2 | c.90G>A p.P30= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs754925425, COSV56851708; called by muse, mutect2
- RAI1 | c.3138G>A p.R1046= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as COSV55389568; called by muse, mutect2, varscan2
- RIPOR1 | c.3624C>T p.A1208= (on ENST00000379312 / NM_001193522.2; = p.A1204= on NM_024519.4) | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs1423765968, COSV50217574; called by muse, mutect2
- RMC1 | c.657C>T p.Y219= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs201101241, COSV52570692; called by muse, mutect2, varscan2
- RPS6KC1 | c.9T>A p.S3= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV65297405; called by muse, mutect2, varscan2
- SALL1 | c.3753G>A p.E1251= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs937264847, COSV51753783; called by muse, mutect2, varscan2
- SBNO1 | c.510G>A p.K170= (on ENST00000420886; = p.K169= on NM_018183.5) | Silent (SNP) | VAF 83/202 reads (41%) | catalogued as COSV99929616; called by muse, mutect2, varscan2
- SERPINI1 | c.786T>C p.V262= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV55508188; called by muse, mutect2, varscan2
- SFMBT1 | c.1899C>T p.T633= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs762424873, COSV56252117; called by muse, mutect2, varscan2
- SLC27A5 | c.84T>C p.A28= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV54018196; called by muse, mutect2, varscan2
- SLFN12 | c.1446A>G p.A482= | Silent (SNP) | VAF 69/330 reads (21%) | catalogued as COSV59225284; called by muse, mutect2, varscan2
- TEX55 | c.618T>G p.T206= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV55210370; called by muse, mutect2
- TUBB8 | c.27C>T p.I9= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs782708970, COSV59114795; called by muse, mutect2, varscan2
- UGT2B28 | c.654T>G p.L218= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV59430782; called by muse, varscan2
- UPK3B | c.48C>T p.L16= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as COSV56859087; called by muse, mutect2, varscan2
- VDR | c.234C>T p.A78= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV57467050; called by muse, mutect2, varscan2
- VPS13D | c.8178C>T p.L2726= | Silent (SNP) | VAF 20/208 reads (10%) | catalogued as rs566696841, COSV99169301; called by muse, mutect2
- ZC3H7A | c.765G>T p.L255= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV63268630, COSV63269691; called by muse, mutect2, varscan2
- ZNF208 | c.627T>G p.A209= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV68101362; called by muse, mutect2, varscan2
- ZNF468 | c.1170A>G p.K390= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV54693441; called by muse, mutect2, varscan2
- ZNF569 | c.1248A>G p.R416= | Silent (SNP) | VAF 34/163 reads (21%) | catalogued as COSV100386621; called by muse, mutect2, varscan2
- ZNF701 | c.1509T>C p.P503= (on ENST00000301093; = p.P437= on NM_018260.3) | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as COSV56523354; called by muse, mutect2, varscan2
- ZSCAN18 | c.783G>T p.L261= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV53730011; called by muse, mutect2, varscan2
- C7orf66 | n.340A>G | RNA (SNP) | VAF 45/160 reads (28%) | called by muse, mutect2, varscan2
- DCHS2 | n.6860T>G | RNA (SNP) | VAF 28/121 reads (23%) | catalogued as COSV61768473; called by muse, mutect2, varscan2
- MIR654 | n.44C>T | RNA (SNP) | VAF 10/37 reads (27%) | catalogued as rs765410808; called by muse, mutect2, varscan2
- RAP1GAP | c.-148-1606C>T | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99265831; called by muse, mutect2
- ZNF618 | c.755-536G>A | Intron (SNP) | VAF 43/174 reads (25%) | catalogued as COSV55916633; called by muse, mutect2, varscan2
